Somatic mutation profile of tumor specimen ALCH-AF1T-TTP1-A (aliquot ALCH-AF1T-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-AF1T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,974 days).
Specimen ALCH-AF1T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 539e24c0-6ffe-46af-b7ec-1c722de3ba1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF1T-NB1-A (Blood Derived Normal), aliquot ALCH-AF1T-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd98518f-6053-4bf9-8d72-25f50dd68c18

The open-access MAF lists 28 somatic variants for this specimen: 14 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 13, Missense Mutation 13, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); catalogued as COSV100290257; called by muse, mutect2, varscan2
- COL6A6 | c.5129G>T p.G1710V | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62022771; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 3/17 reads (18%) | catalogued as rs754135731; called by mutect2, varscan2*
- IPO5 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1053814, COSV55153543, COSV55155230; called by muse, mutect2
- SLITRK5 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs533532510, COSV61521319, COSV61525109; called by muse, mutect2
- ATXN3L | c.984C>A p.D328E | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.013); called by muse, mutect2
- CMYA5 | c.8821A>C p.K2941Q | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- FOXN3 | c.425A>C p.N142T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2
- IMMP2L | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- KCNB1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- NNT | c.1752G>T p.M584I | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SUPT5H | c.1681C>G p.L561V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- TNNI3 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRIM69 | c.499C>G p.Q167E (on ENST00000329464 / NM_182985.5; = p.Q8E on NM_080745.5) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- AK5 | c.996T>C p.L332= (on ENST00000354567 / NM_174858.3; = p.L306= on NM_012093.4) | Silent (SNP) | VAF 30/508 reads (6%) | called by muse, mutect2
- CHAMP1 | c.1155A>T p.A385= | Silent (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- DCN | c.555G>A p.P185= | Silent (SNP) | VAF 31/538 reads (6%) | catalogued as rs147765043; called by muse, mutect2
- DDO | c.661C>T p.L221= (on ENST00000368924 / NM_001368172.1; = p.L162= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- DEFB119 | c.126C>T p.N42= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as rs112690953; called by muse, mutect2
- EFNA2 | c.369G>A p.P123= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- OR5I1 | c.801G>A p.L267= | Silent (SNP) | VAF 16/229 reads (7%) | catalogued as COSV56885855; called by muse, mutect2
- PLRG1 | c.198A>G p.K66= | Silent (SNP) | VAF 36/531 reads (7%) | called by muse, mutect2
- RETSAT | c.834C>T p.H278= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as rs1248720774; called by muse, mutect2
- THBS4 | c.900A>G p.Q300= | Silent (SNP) | VAF 32/296 reads (11%) | catalogued as rs527553801; called by muse, mutect2, varscan2
- THOC2 | c.4464C>T p.N1488= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as rs1353070161; called by muse, mutect2
- UBIAD1 | c.372A>C p.R124= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- ZNF142 | c.5568A>G p.K1856= (on ENST00000411696 / NM_001379660.1; = p.K1656= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- NDUFB9 | c.295-18G>C | Intron (SNP) | VAF 15/336 reads (4%) | called by muse, mutect2
